Somatic mutation profile of tumor specimen TCGA-2G-AAFM-01A (aliquot TCGA-2G-AAFM-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAFM, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 31.8 years (11,607 days).
Specimen TCGA-2G-AAFM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90899a4d-edfb-4520-9f11-b1a3af51ec41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFM-10A (Blood Derived Normal), aliquot TCGA-2G-AAFM-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebcc9796-27c5-444a-aa60-72d2dd4275e6

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 2, Silent 1, 5'UTR 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR8 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as rs375966881; called by muse, mutect2, varscan2
- BAZ2A | c.3742del p.L1248Wfs*26 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as COSV51632952; called by mutect2, pindel, varscan2
- GRK1 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.788); catalogued as rs184639495; called by muse, mutect2, varscan2
- PCDHB4 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99522476; called by muse, mutect2, varscan2
- PIP4P2 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1278197706; called by muse, mutect2, varscan2
- VSIG4 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101038076; called by muse, mutect2, varscan2
- ACBD3 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK2 | c.9016C>T p.P3006S | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CARD8 | c.1460A>T p.E487V (on ENST00000651546 / NM_001184900.3; = p.E437V on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDHGA8 | c.988A>G p.R330G | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PLEC | c.12945G>T p.W4315C (on ENST00000322810 / NM_201380.4; = p.W4205C on NM_000445.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PVR | c.802_804del p.A268del | In Frame Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- SELL | c.33C>G p.S11R | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.001); called by muse, mutect2
- SLC4A7 | c.75C>A p.S25R | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.084); called by muse, mutect2
- SPIB | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- USP40 | c.3229A>G p.I1077V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- ANAPC1 | c.5667C>T p.L1889= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs772269461, COSV61977217; called by mutect2, varscan2
- GABRB1 | c.240+253G>C | Intron (SNP) | VAF 4/101 reads (4%) | catalogued as rs1218363906; called by muse, mutect2
- PTPRZ1 | c.-10C>A | 5'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- RPS19BP1 | c.181+41G>A | Intron (SNP) | VAF 22/214 reads (10%) | called by muse, mutect2
